Somatic mutation profile of tumor specimen ALCH-AESG-TTP1-A (aliquot ALCH-AESG-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AESG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.5 years (23,566 days).
Specimen ALCH-AESG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 043171f9-7b8b-4860-b09b-2fd501cb7b14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AESG-NB1-A (Blood Derived Normal), aliquot ALCH-AESG-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d75b0700-5acf-437a-b391-c56d7edd2a28

The open-access MAF lists 198 somatic variants for this specimen: 126 protein-altering or splice-affecting, 48 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 48, Intron 16, Splice Site 5, Nonsense Mutation 4, 3'UTR 3, Splice Region 3, Frame Shift Del 3, 5'UTR 3, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 64/387 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANK3 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 30/288 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1371476805, COSV55081736; called by muse, varscan2
- ANKEF1 | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs139757926; called by muse, mutect2, varscan2
- APOB | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 34/142 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs746414462, COSV51927055; ClinVar: likely benign; called by muse, mutect2
- ATRX | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.824); catalogued as rs781865069; ClinVar: likely benign; called by muse, mutect2, varscan2
- C4orf54 | c.1007G>A p.G336E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.007); catalogued as rs1020828481; called by muse, mutect2, varscan2
- C9orf43 | c.793C>T p.R265C | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as rs148905915, COSV55914311; called by muse, mutect2, varscan2
- CCR10 | c.211C>T p.R71C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs748303358, COSV52854248; called by mutect2, varscan2
- CDK5RAP2 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 75/332 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1318013964; called by muse, mutect2, varscan2
- CELSR3 | c.3538G>A p.V1180I | Missense Mutation (SNP) | VAF 96/451 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.13); catalogued as rs1443237457; called by muse, mutect2, varscan2
- CEP104 | c.1634G>A p.R545H | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1448095441; called by muse, mutect2, varscan2
- CLIC1 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs1450247645; called by muse, mutect2, varscan2
- COL12A1 | c.4945C>G p.Q1649E | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59391644; called by muse, mutect2, varscan2
- CSNK2A1 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as rs1240575566, COSV53936074; called by muse, mutect2, varscan2
- CUBN | c.6070C>G p.L2024V | Missense Mutation (SNP) | VAF 37/542 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.249); catalogued as COSV64709497; called by muse, mutect2
- DNER | c.1871C>A p.S624Y | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.687); catalogued as COSV100518816, COSV59163034; called by muse, mutect2, varscan2
- DSG3 | c.8G>C p.G3A | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1295987429; called by muse, mutect2, varscan2
- ERICH3 | c.4345G>C p.E1449Q | Missense Mutation (SNP) | VAF 41/181 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs765485840; called by muse, mutect2, varscan2
- FAM184A | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV58855873; called by muse, mutect2, varscan2
- FASN | c.6077G>T p.R2026L | Missense Mutation (SNP) | VAF 53/258 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60757023; called by muse, mutect2, varscan2
- FLG | c.2410G>A p.E804K | Missense Mutation (SNP) | VAF 24/421 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV64235891; called by muse, mutect2
- GTF2IRD2B | c.1470A>T p.K490N | Missense Mutation (SNP) | VAF 51/775 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs1305508436; called by muse, mutect2
- HECW1 | c.1183C>A p.Q395K | Missense Mutation (SNP) | VAF 24/258 reads (9%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as rs531733998, COSV67838523; called by muse, mutect2
- HMCN1 | c.1204T>C p.F402L | Missense Mutation (SNP) | VAF 78/469 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.664); catalogued as COSV99630983; called by muse, mutect2, varscan2
- ID1 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as rs1231671714, COSV65888297; called by muse, mutect2
- JPH3 | c.2051G>C p.G684A | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.705); catalogued as rs1567616485; called by muse, mutect2, varscan2
- KIFC3 | c.1873G>A p.V625M | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.97); catalogued as rs900944472; called by muse, mutect2, varscan2
- L3MBTL2 | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs765453159, COSV99345541; called by muse, varscan2
- LAMA4 | c.1034C>T p.T345M (on ENST00000230538 / NM_001105206.3; = p.T338M on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/516 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs781832612; called by muse, mutect2, varscan2
- LOXL2 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.874); catalogued as rs775789952, COSV66692050; called by muse, mutect2, varscan2
- LRGUK | c.71G>C p.R24P | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); catalogued as COSV53640341; called by muse, mutect2
- MAPK8IP2 | c.1948G>T p.G650W | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50509419; called by muse, mutect2, varscan2
- MCM6 | c.542G>T p.R181L | Missense Mutation (SNP) | VAF 102/503 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.241); catalogued as COSV51466836; called by muse, mutect2, varscan2
- MYO16 | c.5293A>G p.I1765V | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1175423817; called by muse, mutect2, varscan2
- NGFR | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 40/360 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.122); catalogued as rs778839148; called by muse, mutect2, varscan2
- ODF1 | c.275G>A p.R92K | Missense Mutation (SNP) | VAF 120/217 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.745); catalogued as COSV53432725; called by muse, mutect2, varscan2
- OTOF | c.2275C>T p.R759C (on ENST00000272371 / NM_194248.3; = p.R12C on NM_004802.4) | Missense Mutation (SNP) | VAF 30/336 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs766182525, COSV55497687, COSV99719413; called by muse, mutect2
- PCSK4 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.401); catalogued as rs760242868; called by mutect2, varscan2
- PFKM | c.1808G>C p.R603P | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV56660258; called by muse, mutect2, varscan2
- PMFBP1 | c.1800C>T p.H600= (on ENST00000537465; = p.H595= on NM_031293.3) | Splice Region (SNP) | VAF 13/143 reads (9%) | catalogued as COSV99400475; called by muse, mutect2
- PPFIA2 | c.2695G>T p.D899Y | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61024144; called by muse, mutect2
- PRDM9 | c.149G>T p.R50L | Missense Mutation (SNP) | VAF 50/604 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as rs772688836; called by muse, mutect2
- RNF103 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 41/282 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1218812053; called by muse, mutect2, varscan2
- RNF121 | c.370C>T p.R124* | Nonsense Mutation (SNP) | VAF 21/99 reads (21%) | catalogued as COSV62318036; called by muse, mutect2, varscan2
- SAMSN1 | c.694A>G p.R232G (on ENST00000647101; = p.R4G on NM_001256370.1) | Missense Mutation (SNP) | VAF 26/170 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as rs756807173; called by muse, mutect2, varscan2
- SHANK2 | c.1491C>T p.V497= | Splice Region (SNP) | VAF 15/21 reads (71%) | catalogued as rs1297667545; called by muse, mutect2
- SLC13A1 | c.185C>G p.P62R | Missense Mutation (SNP) | VAF 37/183 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52018562; called by muse, mutect2, varscan2
- SPOP | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 57/319 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV61654573; called by muse, mutect2, varscan2
- TFDP1 | c.505G>A p.V169I | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs1341133643, COSV64740023; called by muse, mutect2, varscan2
- TMEM240 | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 58/183 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.698); catalogued as rs755349243; called by muse, mutect2, varscan2
- TRABD2A | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.122); catalogued as rs372746235; called by muse, mutect2, varscan2
- TUBGCP6 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as rs968790589, COSV50592946; called by muse, mutect2
- UBE2C | c.217-1G>C p.X73_splice | Splice Site (SNP) | VAF 45/380 reads (12%) | catalogued as COSV54754857; called by muse, mutect2, varscan2
- WDCP | c.2087C>G p.S696C | Missense Mutation (SNP) | VAF 96/421 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99721959; called by muse, mutect2, varscan2
- ZNF407 | c.4168C>T p.P1390S | Missense Mutation (SNP) | VAF 44/372 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs776452928; called by muse, mutect2, varscan2
- ZNF85 | c.1769G>T p.G590V | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV60217809; called by muse, mutect2, varscan2
- ADGRL1 | c.2981+1G>A p.X994_splice (on ENST00000340736 / NM_001008701.3; = p.X989_splice on NM_014921.5) | Splice Site (SNP) | VAF 19/141 reads (13%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2702C>A p.S901* (on ENST00000506720 / NM_001322402.2; = p.S833* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 50/316 reads (16%) | called by muse, mutect2, varscan2
- AEBP2 | c.1210G>A p.D404N | Missense Mutation (SNP) | VAF 46/458 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); called by muse, mutect2
- ANK3 | c.2889C>A p.Y963* (on ENST00000280772 / NM_001320874.2; = p.Y97* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 112/322 reads (35%) | called by muse, varscan2
- ANKFN1 | c.62+7A>G | Splice Region (SNP) | VAF 34/232 reads (15%) | called by muse, varscan2
- ANKRD13B | c.545G>A p.S182N | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ATP1A2 | c.1400A>T p.K467I | Missense Mutation (SNP) | VAF 147/601 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BFSP1 | c.1720G>T p.A574S | Missense Mutation (SNP) | VAF 24/229 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.009); called by muse, mutect2
- C14orf93 | c.86A>G p.N29S | Missense Mutation (SNP) | VAF 18/187 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- C16orf82 | c.27del p.I10Ffs*27 | Frame Shift Del (DEL) | VAF 70/337 reads (21%) | called by mutect2, pindel, varscan2
- CFAP52 | c.1149G>T p.M383I | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, varscan2
- CIC | c.528_529del p.L177Tfs*9 | Frame Shift Del (DEL) | VAF 46/448 reads (10%) | called by mutect2, pindel, varscan2
- CNR1 | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 13/203 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2
- CNTLN | c.1732G>C p.E578Q | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.367); called by muse, mutect2
- CNTNAP3 | c.2876C>T p.A959V | Missense Mutation (SNP) | VAF 32/622 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- COBL | c.2358C>A p.S786R | Missense Mutation (SNP) | VAF 34/154 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CRB1 | c.3552C>A p.N1184K | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- DBH | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DHX8 | c.2407G>A p.D803N | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAM171B | c.520A>G p.I174V | Missense Mutation (SNP) | VAF 11/232 reads (5%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.898); called by muse, mutect2
- FAT2 | c.6947C>G p.S2316* | Nonsense Mutation (SNP) | VAF 43/280 reads (15%) | called by muse, mutect2, varscan2
- FBXO21 | c.705A>G p.I235M | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXF1 | c.283T>C p.S95P | Missense Mutation (SNP) | VAF 34/383 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- FRA10AC1 | c.230A>T p.H77L | Missense Mutation (SNP) | VAF 27/228 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GUCY2C | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- HCN1 | c.2126A>G p.Q709R | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- HHLA1 | c.62T>C p.L21S | Missense Mutation (SNP) | VAF 51/413 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- HSP90AA1 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 42/365 reads (12%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- HTATSF1 | c.1547G>C p.G516A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- INSL4 | c.20C>A p.S7Y | Missense Mutation (SNP) | VAF 37/126 reads (29%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- INTS1 | c.2402G>C p.R801P | Missense Mutation (SNP) | VAF 49/279 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- IRF3 | c.838T>C p.W280R | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- JAK2 | c.1039C>G p.Q347E | Missense Mutation (SNP) | VAF 83/279 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- KCNA4 | c.1530C>A p.S510R | Missense Mutation (SNP) | VAF 64/282 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL1 | c.36G>C p.K12N | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LAMA3 | c.3499G>C p.G1167R | Missense Mutation (SNP) | VAF 154/673 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- LY6G6E | c.258C>G p.H86Q | Missense Mutation (SNP) | VAF 32/371 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- MAP1A | c.5059G>A p.E1687K | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.359); called by muse, mutect2
- MBD2 | c.779C>T p.T260I | Missense Mutation (SNP) | VAF 41/350 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.54); called by muse, mutect2, varscan2
- MED24 | c.1547C>T p.S516L | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.027); called by muse, mutect2
- MIER3 | c.733A>T p.R245W | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2
- MORC1 | c.1702C>A p.Q568K | Missense Mutation (SNP) | VAF 28/620 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- MRC1 | c.3356C>T p.A1119V | Missense Mutation (SNP) | VAF 48/642 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH13 | c.1413+1G>A p.X471_splice | Splice Site (SNP) | VAF 52/300 reads (17%) | called by muse, mutect2, varscan2
- NLRP12 | c.2922A>C p.K974N | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.878); called by muse, mutect2
- NPHS1 | c.1951G>C p.E651Q | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.191); called by muse, mutect2
- NRCAM | c.441G>T p.W147C (on ENST00000379028 / NM_001371124.1; = p.W141C on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR2A5 | c.694G>C p.E232Q | Missense Mutation (SNP) | VAF 72/413 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- OR51M1 | c.863T>A p.M288K | Missense Mutation (SNP) | VAF 59/324 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PKHD1L1 | c.7429C>A p.H2477N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PRSS1 | c.536T>C p.I179T | Missense Mutation (SNP) | VAF 89/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- RAG2 | c.1111G>C p.D371H | Missense Mutation (SNP) | VAF 43/608 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RXFP1 | c.25T>A p.Y9N | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.48); called by muse, mutect2
- SH2B2 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SHANK3 | c.4901C>T p.P1634L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC18A2 | c.350G>T p.C117F | Missense Mutation (SNP) | VAF 40/484 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SORL1 | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); called by muse, mutect2
- STAP1 | c.638T>A p.I213N | Missense Mutation (SNP) | VAF 36/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SUGCT | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 58/354 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, varscan2
- TEX14 | c.4252G>A p.E1418K (on ENST00000240361 / NM_001201457.2; = p.E1372K on NM_031272.5) | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- TIGD7 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRIM58 | c.1079T>C p.L360S | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPM5 | c.1576G>T p.V526L | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.045); called by muse, mutect2
- USP9X | c.7336G>A p.V2446M | Missense Mutation (SNP) | VAF 68/325 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- VCAN | c.4556C>T p.A1519V | Missense Mutation (SNP) | VAF 33/220 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- VPS13A | c.7026+1G>A p.X2342_splice | Splice Site (SNP) | VAF 29/251 reads (12%) | called by muse, mutect2, varscan2
- ZNF184 | c.1268G>C p.C423S | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF335 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 45/216 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF791 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 42/232 reads (18%) | called by muse, varscan2
- ZNF831 | c.2570del p.K857Sfs*38 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel, varscan2
- ABCG1 | c.1593C>T p.A531= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs779369839, COSV100494044; called by muse, mutect2, varscan2
- ACAN | c.7266C>A p.I2422= (on ENST00000560601 / NM_001369268.1; = p.I2346= on NM_001135.3) | Silent (SNP) | VAF 31/239 reads (13%) | catalogued as COSV61369018; called by muse, mutect2, varscan2
- ANKDD1B | c.1149G>A p.V383= | Silent (SNP) | VAF 20/364 reads (5%) | called by muse, mutect2
- ANKLE2 | c.1560G>A p.L520= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as COSV61707935, COSV61709150; called by muse, mutect2, varscan2
- CAPN8 | c.408G>A p.A136= | Silent (SNP) | VAF 20/210 reads (10%) | catalogued as rs1015134423; called by muse, mutect2
- CCT6A | c.777C>T p.L259= | Silent (SNP) | VAF 35/191 reads (18%) | catalogued as rs201586656, COSV51907603; called by muse, mutect2, varscan2
- CDRT1 | c.156A>G p.S52= | Silent (SNP) | VAF 40/308 reads (13%) | called by muse, mutect2, varscan2
- CILP | c.327C>T p.V109= | Silent (SNP) | VAF 22/312 reads (7%) | catalogued as COSV56026783; called by muse, mutect2
- CLMN | c.1113G>T p.A371= | Silent (SNP) | VAF 55/206 reads (27%) | catalogued as rs753946996, COSV54183061; called by muse, mutect2, varscan2
- CROCC2 | c.3441C>T p.A1147= | Silent (SNP) | VAF 17/100 reads (17%) | catalogued as rs1252965199; called by muse, mutect2, varscan2
- FAM160A2 | c.2829G>A p.Q943= (on ENST00000449352 / NM_001098794.2; = p.Q957= on NM_032127.4) | Silent (SNP) | VAF 25/205 reads (12%) | called by muse, mutect2, varscan2
- GABRA2 | c.378C>G p.T126= | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- HPGD | c.726T>A p.I242= | Silent (SNP) | VAF 43/395 reads (11%) | called by muse, mutect2, varscan2
- HPS3 | c.1200G>A p.A400= | Silent (SNP) | VAF 58/756 reads (8%) | catalogued as rs377368442, COSV56052782; called by muse, mutect2
- KPNB1 | c.489A>G p.P163= | Silent (SNP) | VAF 27/109 reads (25%) | called by muse, mutect2, varscan2
- LMTK3 | c.2907G>A p.R969= | Silent (SNP) | VAF 20/171 reads (12%) | called by muse, mutect2, varscan2
- LY75 | c.45C>T p.L15= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.216C>T p.H72= | Silent (SNP) | VAF 58/224 reads (26%) | called by muse, mutect2, varscan2
- MECOM | c.1317G>A p.Q439= (on ENST00000468789 / NM_001105078.4; = p.Q627= on NM_004991.4) | Silent (SNP) | VAF 125/761 reads (16%) | called by muse, mutect2, varscan2
- MIEF1 | c.1170C>T p.L390= | Silent (SNP) | VAF 55/281 reads (20%) | catalogued as rs201698844; called by muse, mutect2, varscan2
- NUP188 | c.1029G>A p.R343= | Silent (SNP) | VAF 61/511 reads (12%) | catalogued as rs964755665, COSV65364861; called by muse, mutect2, varscan2
- OR8H2 | c.594G>C p.L198= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- PALB2 | c.2508C>G p.V836= | Silent (SNP) | VAF 40/510 reads (8%) | catalogued as rs786203603; ClinVar: likely benign; called by muse, mutect2
- PCLO | c.1536A>G p.Q512= | Silent (SNP) | VAF 91/574 reads (16%) | called by muse, mutect2, varscan2
- PCLO | c.57C>G p.A19= | Silent (SNP) | VAF 15/149 reads (10%) | called by muse, mutect2, varscan2
- PCSK4 | c.579C>G p.P193= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- PRSS27 | c.795C>T p.V265= | Silent (SNP) | VAF 12/89 reads (13%) | called by muse, mutect2, varscan2
- PSMD9 | c.72G>A p.Q24= | Silent (SNP) | VAF 19/195 reads (10%) | called by muse, mutect2
- SKIV2L | c.897C>T p.L299= | Silent (SNP) | VAF 15/115 reads (13%) | catalogued as rs765052945; called by muse, mutect2, varscan2
- SLC25A48 | c.429C>T p.L143= (on ENST00000650267; = p.L89= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as rs758713627, COSV50848107; called by muse, mutect2
- SLC7A4 | c.630C>T p.V210= | Silent (SNP) | VAF 9/127 reads (7%) | catalogued as COSV60385181; called by muse, mutect2
- SPAM1 | c.1131C>T p.S377= | Silent (SNP) | VAF 19/246 reads (8%) | called by muse, mutect2
- SPANXN2 | c.243C>A p.V81= | Silent (SNP) | VAF 80/420 reads (19%) | catalogued as COSV65128927; called by muse, varscan2
- SPATA45 | c.123C>A p.V41= | Silent (SNP) | VAF 65/549 reads (12%) | catalogued as COSV60572270; called by muse, varscan2
- SULT1C3 | c.120T>C p.C40= | Silent (SNP) | VAF 17/81 reads (21%) | called by muse, mutect2, varscan2
- TAS2R60 | c.474A>T p.L158= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- TEX19 | c.354C>T p.H118= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV61017641; called by muse, mutect2
- THNSL2 | c.147C>G p.L49= | Silent (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- TLX2 | c.546G>A p.L182= | Silent (SNP) | VAF 10/175 reads (6%) | called by muse, mutect2
- TPST1 | c.882C>G p.V294= | Silent (SNP) | VAF 23/231 reads (10%) | catalogued as COSV100507402; called by muse, mutect2, varscan2
- TRIM58 | c.1248C>T p.D416= | Silent (SNP) | VAF 34/375 reads (9%) | called by muse, mutect2
- TSNAXIP1 | c.15G>T p.L5= | Silent (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- TTN | c.10194T>A p.T3398= (on ENST00000591111; = p.T3352= on NM_003319.4) | Silent (SNP) | VAF 24/332 reads (7%) | called by muse, mutect2
- WDFY3 | c.9810A>G p.P3270= | Silent (SNP) | VAF 48/323 reads (15%) | called by muse, mutect2, varscan2
- ZBTB32 | c.1318C>T p.L440= | Silent (SNP) | VAF 228/346 reads (66%) | called by muse, mutect2, varscan2
- ZNF462 | c.6063C>T p.R2021= | Silent (SNP) | VAF 63/495 reads (13%) | catalogued as rs376720857; called by muse, mutect2, varscan2
- ZNF705A | c.828A>T p.I276= | Silent (SNP) | VAF 46/480 reads (10%) | called by muse, mutect2, varscan2
- ZNF80 | c.117A>G p.K39= | Silent (SNP) | VAF 44/270 reads (16%) | called by muse, mutect2
- ABI3BP | c.1577-5447G>A | Intron (SNP) | VAF 18/282 reads (6%) | called by muse, mutect2
- ACSM2B | c.597-169C>G | Intron (SNP) | VAF 86/454 reads (19%) | called by muse, mutect2, varscan2
- ARHGDIA | c.*136G>C | 3'UTR (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-109+159C>T | Intron (SNP) | VAF 19/162 reads (12%) | catalogued as rs1356749052; called by muse, mutect2, varscan2
- C8orf86 | n.648C>G | RNA (SNP) | VAF 24/332 reads (7%) | called by muse, mutect2
- COL18A1 | c.3928+724G>A | Intron (SNP) | VAF 30/304 reads (10%) | catalogued as rs779037894, COSV100645448; called by muse, mutect2, varscan2
- COP1 | c.2133+18448C>T | Intron (SNP) | VAF 57/221 reads (26%) | called by muse, mutect2, varscan2
- CSMD3 | c.178+59875C>A | Intron (SNP) | VAF 125/630 reads (20%) | catalogued as COSV52207128; called by muse, mutect2, varscan2
- EIF2B4 | c.76-31G>A | Intron (SNP) | VAF 50/544 reads (9%) | called by muse, mutect2
- FCN1 | c.*260C>A | 3'UTR (SNP) | VAF 29/211 reads (14%) | called by muse, mutect2, varscan2
- MEIS1 | c.743-3115G>T | Intron (SNP) | VAF 13/395 reads (3%) | called by muse, mutect2
- NRXN3 | c.3262+10A>G | Intron (SNP) | VAF 15/353 reads (4%) | called by muse, mutect2
- RALGAPA1 | c.2267-10184C>T | Intron (SNP) | VAF 41/169 reads (24%) | called by muse, mutect2, varscan2
- RANBP1 | c.505+237C>G | Intron (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- RNH1 | c.443+263G>A | Intron (SNP) | VAF 21/77 reads (27%) | catalogued as rs781658154; called by muse, mutect2, varscan2
- SERTAD4 | c.-18+829G>A | Intron (SNP) | VAF 16/125 reads (13%) | called by muse, mutect2, varscan2
- SMG6 | c.-45C>T | 5'UTR (SNP) | VAF 16/81 reads (20%) | catalogued as rs1348205641; called by muse, mutect2, varscan2
- TIMM50 | c.372+19C>T | Intron (SNP) | VAF 30/217 reads (14%) | catalogued as rs1480565396; called by muse, mutect2, varscan2
- TMEM161A | c.-46G>C | 5'UTR (SNP) | VAF 22/162 reads (14%) | catalogued as rs778066734; called by muse, mutect2, varscan2
- TMEM39A | c.420+1187G>C | Intron (SNP) | VAF 65/294 reads (22%) | called by muse, mutect2, varscan2
- TUBB8P7 | n.605G>T | RNA (SNP) | VAF 44/374 reads (12%) | called by muse, mutect2, varscan2
- ZFHX4 | c.3093+106dup | Intron (INS) | VAF 21/90 reads (23%) | catalogued as rs371323510; called by mutect2, pindel, varscan2
- ZNF549 | c.-83C>T | 5'UTR (SNP) | VAF 11/142 reads (8%) | called by muse, mutect2
- ZNF99 | c.*3192A>C | 3'UTR (SNP) | VAF 10/155 reads (6%) | called by muse, mutect2
